FM case AD1778 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/ffd51178-2e55-471c-a486-83fed564023a

Female, 55.2 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
